Gene-level copy-number profile of tumor specimen TCGA-29-1770-01A from TCGA case TCGA-29-1770, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.8 years (20,015 days).
Specimen TCGA-29-1770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9f90944b-ee3c-4f43-93b1-e2bf5829a325.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1770-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dfb1cae9-197e-4c72-8b73-b14c372690d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 2,050; copy number 2: 20,985; copy number 3: 18,504; copy number 4: 12,516; copy number 5: 3,356; copy number 6: 768; copy number 7: 102; copy number 8: 309; copy number 9: 702; copy number 10: 507.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1770-01A-01D-0559-01): tumor purity 0.73, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,750,430–8,807,051, 5 genes: RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2.
- chr6:138,422,043–138,692,571, 1 gene (within-gene range 0–2): NHSL1.
- chr6:138,650,226–139,291,998, 13 genes: AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,744 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,488,193–68,282,622, 955 genes, copy number 5 (broad region; genes not listed).
- chr1:143,343,180–166,452,632, 931 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:216,503,246–246,507,312, 607 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:81,986,138–90,261,708, 54 genes, copy number 5: LINC02008, RPL7AP23, CYP51A1P1, AC023503.1, AC092825.1, SRRM1P2, AC117464.1, LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:99,326,377–190,832,173, 1,527 genes, copy number 5–6 (broad region; genes not listed).
- chr4:181,064,089–182,145,249, 10 genes, copy number 6 (within-gene range 3–6): LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr5:58,198–38,198,148, 590 genes, copy number 5–9 (broad region; genes not listed).
- chr8:103,371,538–145,066,685, 612 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr15:31,923,438–32,173,018, 1 gene, copy number 5 (within-gene range 3–5): CHRNA7.
- chr15:32,175,247–33,194,714, 36 genes, copy number 5 (within-gene range 4–5): Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, AC139426.4, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3, AC123768.2, GOLGA8N, RN7SL286P, AC123768.1, ARHGAP11A, AC123768.4, SCG5, SCG5-AS1, AC090877.2, GREM1, FMN1, AC090877.1, AC018515.1, HNRNPA1P71.
- chr20:46,709,649–64,313,132, 421 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,050. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
